Gene-level copy-number profile of specimen HCM-WCMC-0751-C54-85A from HCMI case HCM-WCMC-0751-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, secretory variant; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 54.6 years (19,958 days).
Specimen HCM-WCMC-0751-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 12.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e7ba84fb-676b-46ba-b9d3-2d8758762bad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0751-C54-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/6fc8d97e-1803-42bf-a705-41b9ca946ee1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 173; copy number 1: 20,769; copy number 2: 32,205; copy number 3: 4,641; copy number 4: 584; copy number 5: 18.

Homozygous deletions (total copy number 0; autosomes only): 173 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,237,358–181,523,001, 3 genes: AC019235.1, LINC02500, AC093840.1.
- chr4:181,874,438–187,712,329, 118 genes (within-gene range 0–1) (broad region; genes not listed).
- chr4:187,970,273–190,092,279, 49 genes: AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr12:113,178,423–113,192,368, 3 genes (within-gene range 0–1): Y_RNA, RITA1, AC089999.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:175,072,250–175,184,607, 7 genes, copy number 5: ATF2, AC007435.1, MIR933, AC096649.1, ATP5MC3, Y_RNA, RPS15AP14.
- chr19:4,007,736–4,269,088, 11 genes, copy number 5: PIAS4, ZBTB7A, AC016586.1, MAP2K2, Metazoa_SRP, CREB3L3, SIRT6, ANKRD24, EBI3, AC005578.1, YJU2.

Autosomal genes at a single copy (total copy number 1): 20,769. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
